Somatic mutation profile of tumor specimen TCGA-EO-A22U-01A (aliquot TCGA-EO-A22U-01A-11D-A17W-09) from TCGA case TCGA-EO-A22U, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 83.7 years (30,557 days).
Specimen TCGA-EO-A22U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3a42a06-a33f-4fef-8483-30cf85bcf1fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A22U-10B (Blood Derived Normal), aliquot TCGA-EO-A22U-10B-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c676f7e1-de13-4c16-b106-a611228881b3

The open-access MAF lists 16,981 somatic variants for this specimen: 12,179 protein-altering or splice-affecting, 4,396 silent, 406 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10,690, Silent 4,396, Nonsense Mutation 956, Splice Site 222, Frame Shift Ins 173, Intron 152, Splice Region 113, RNA 111, 3'UTR 56, 3'Flank 35, 5'Flank 28, 5'UTR 24.

Variants (750 of 16,981; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADM | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs121434279, CM970026, COSV57714629; ClinVar: likely pathogenic; called by muse, varscan2
- ACER3 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | catalogued as rs782709009; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.6610C>T p.R2204* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as rs752654519, COSV57326468, COSV99965912; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ASL | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.458); catalogued as rs751590073, CM022318; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- BRD7 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as rs796065051, COSV54264750; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CACNA1G | c.5144G>A p.R1715H | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755221106, CM1511857, COSV100662400; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- CEP55 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as rs141458677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A1 | c.324+1G>A p.X108_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as rs1085307816, COSV65429258; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 10/89 reads (11%) | catalogued as rs587783464, CM053181, COSV52142374; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 34/84 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV62698994; called by muse, mutect2, varscan2
- CTSC | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as rs104894206, CM993131; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DCX | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs587783529, COSV57571769, COSV57574866; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.5441C>T p.S1814L | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1060503625, CM1511756, COSV58630883; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DOCK8 | c.4162C>T p.R1388* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as rs1476130680, CM153400; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ECEL1 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.413); catalogued as rs765430577, CM130311; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EDA | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.183); catalogued as rs397516662, CM011770, COSV104424050; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EDARADD | c.196C>T p.R66* (on ENST00000334232 / NM_145861.4; = p.R56* on NM_080738.4) | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as rs766500689; ClinVar: pathogenic; called by muse, varscan2
- ERBB3 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 18/37 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1035001455, COSV57246372; called by muse, mutect2, varscan2
- ERCC2 | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs41556519, CM950365; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ETFB | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs548046212, COSV58537541; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGD1 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs28935497, CM002015; ClinVar: pathogenic; called by muse, varscan2
- FGD4 | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as rs118203974, CM090824; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGF3 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as rs121917704, CM070117, COSV100490202; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FRAS1 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as rs377046630, CM118795; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GFM1 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as rs863224032; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNS | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | catalogued as rs119461974, CM030467, COSV50697172; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HCCS | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs193929392, CM074272; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HMBS | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs118204110, CM940941; ClinVar: likely pathogenic; called by muse, varscan2
- KCNQ1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199472763, CM043852, CM970828; ClinVar: not provided / pathogenic; called by muse, varscan2
- KMT2D | c.14710C>T p.R4904* | Nonsense Mutation (SNP) | VAF 20/44 reads (45%) | catalogued as rs398123721, CM105476, COSV56414273; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.7933C>T p.R2645* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as rs1555191740, CM111915, COSV56409935; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAT1A | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs72558181, CM970910, COSV64745225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 41/109 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- MECP2 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 35/85 reads (41%) | catalogued as rs61751362, CM000750, CM023745, CX130322; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, varscan2
- MFF | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as rs753829320, CM162801, COSV58825753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MPI | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs863225087, CM002368, COSV60396305; ClinVar: pathogenic; called by muse, varscan2
- MTM1 | c.679-1G>A p.X227_splice | Splice Site (SNP) | VAF 16/44 reads (36%) | catalogued as rs672601324, CS971810; ClinVar: likely pathogenic; called by muse, varscan2
- MYH7 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs397516127, CM031273, CM973126, COSV62516387; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.2914C>T p.R972* | Nonsense Mutation (SNP) | VAF 29/81 reads (36%) | catalogued as rs782281371, CM081714, COSV101289259, COSV68687619; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NDUFS7 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs11551664; ClinVar: likely pathogenic; called by muse, varscan2
- NEXMIF | c.1014dup p.P339Sfs*13 | Frame Shift Ins (INS) | VAF 7/33 reads (21%) | catalogued as rs1556016723; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.4084C>T p.R1362* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as rs137854560, CM971046, COSV62191433, COSV62213078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAK3 | c.1300C>T p.R434* (on ENST00000262836 / NM_001324328.2; = p.R419* on NM_002578.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as rs121434611, CM981458, COSV53273940; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCNT | c.7819C>T p.R2607* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as rs749426946, COSV64032579; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 19/54 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV55874903, COSV99836298; called by muse, mutect2, varscan2
- PIK3CA | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as rs1064793732, CM126690, COSV55881636, COSV55977337; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLA2G6 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs587784363; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PLCE1 | c.6448C>T p.R2150* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as rs267606953, CM104675, COSV53376898; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.1687C>T p.R563* | Nonsense Mutation (SNP) | VAF 27/84 reads (32%) | catalogued as rs587778618, CM102799, COSV56221094, COSV56222163; ClinVar: pathogenic / not provided; called by muse, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 19/40 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PRKG1 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs397515330, CM137218; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PRX | c.2689C>T p.R897* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as rs756689732, CM1411882, COSV52532630; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- PTEN | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as rs1114167674, CM110151, COSV64293312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.3277C>T p.R1093* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as rs121912628, CM092910, COSV54748338; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RANBP2 | c.1966A>G p.I656V | Missense Mutation (SNP) | VAF 101/290 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs121434504, CM090150; ClinVar: pathogenic; called by muse, varscan2
- RPS6KA3 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs122454127, CM992428, COSV65387529; ClinVar: pathogenic; called by muse, varscan2
- SCN1A | c.1118dup p.L373Ffs*77 | Frame Shift Ins (INS) | VAF 21/69 reads (30%) | catalogued as rs794726695; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SCN5A | c.4070C>T p.A1357V (on ENST00000333535 / NM_198056.3; = p.A1356V on NM_000335.5) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370588133, CM139917; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- SIPA1L3 | c.4489C>T p.R1497* | Nonsense Mutation (SNP) | VAF 29/66 reads (44%) | catalogued as rs756898971, CM1511434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC12A3 | c.3025C>T p.R1009* (on ENST00000563236 / NM_001126108.2; = p.R1018* on NM_000339.3) | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | catalogued as rs781209989, CM034686; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC2A2 | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as rs121909742, CM971383, COSV58585414; ClinVar: pathogenic; called by mutect2, varscan2
- SPTBN2 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514749, CM1314430, COSV59457011; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TAB2 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 24/71 reads (34%) | catalogued as rs1479104927; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TMEM67 | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 27/62 reads (44%) | catalogued as rs751517725, COSV60036110; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMPRSS3 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs200090033, CM140338; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.85774C>T p.R28592* (on ENST00000591111; = p.R21168* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as rs1553539391, COSV60169898; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TTN | c.56008C>T p.R18670* (on ENST00000591111; = p.R11246* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as rs869312055, CM1514595, COSV59955046; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TUBB4B | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.789); catalogued as rs1554786803; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TYR | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121908011, CM900223, COSV54474986; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.4474G>T p.E1492* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as rs869312179, CM058338; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VPS33B | c.1594C>T p.R532* | Nonsense Mutation (SNP) | VAF 29/79 reads (37%) | catalogued as rs121434383, CM041100; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZNF423 | c.3274G>A p.V1092I (on ENST00000563137 / NM_001379286.1; = p.V1084I on NM_015069.4) | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs759221881, COSV52177673; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59385447; called by muse, mutect2, varscan2
- A2ML1 | c.4034G>A p.R1345Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs1388303934, COSV55285428; called by muse, mutect2, varscan2
- A4GALT | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs754861621, COSV50746909; called by muse, mutect2, varscan2
- A4GNT | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1347276647; called by muse, mutect2, varscan2
- AACS | c.1881G>A p.P627= | Splice Region (SNP) | VAF 27/46 reads (59%) | catalogued as rs1176060203; called by muse, mutect2, varscan2
- AADACL3 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.329); catalogued as rs748929112, COSV100206829, COSV60198875; called by muse, varscan2
- AADAT | c.901-1G>T p.X301_splice | Splice Site (SNP) | VAF 23/45 reads (51%) | catalogued as COSV61788130; called by muse, mutect2, varscan2
- AAK1 | c.2425C>T p.P809S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1049224462; called by muse, mutect2, varscan2
- AARS2 | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs141973247; called by muse, varscan2
- AASDH | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as rs778828612, COSV52710622; called by mutect2, varscan2
- AASS | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1449180976; called by muse, mutect2, varscan2
- ABAT | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs778974775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA1 | c.4219G>A p.A1407T | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as rs189206655, COSV66064966; called by muse, mutect2, varscan2
- ABCA10 | c.4337A>C p.Q1446P | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99289158; called by muse, mutect2, varscan2
- ABCA10 | c.1529G>T p.R510I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV52219460; called by muse, mutect2, varscan2
- ABCA13 | c.5641G>A p.E1881K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as COSV70026288, COSV70048767; called by muse, mutect2, varscan2
- ABCA13 | c.9343G>T p.V3115L | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV71286417; called by muse, mutect2, varscan2
- ABCA13 | c.12926G>A p.R4309H | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771458235, COSV68947596; called by muse, mutect2, varscan2
- ABCA2 | c.5171G>A p.R1724Q (on ENST00000614293; = p.R1694Q on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1010778970, COSV55799931, COSV55807147; called by muse, mutect2, varscan2
- ABCA2 | c.4633G>A p.E1545K (on ENST00000614293; = p.E1515K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs1389978024; called by muse, mutect2, varscan2
- ABCA3 | c.2408C>T p.T803M | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.296); catalogued as rs748819386, CM1413479, COSV100068148; called by muse, mutect2, varscan2
- ABCA4 | c.6439G>A p.A2147T | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs966835207, COSV100933037; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA4 | c.4405A>G p.N1469D | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs769441167; called by muse, mutect2, varscan2
- ABCA5 | c.4505G>A p.R1502Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1375340645, COSV67019489; called by muse, mutect2, varscan2
- ABCA5 | c.3639G>A p.S1213= | Splice Region (SNP) | VAF 20/44 reads (45%) | catalogued as rs778958910, COSV67018547; called by muse, mutect2, varscan2
- ABCA5 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.63); catalogued as rs1198500028; called by muse, mutect2, varscan2
- ABCA5 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as rs1180912574, COSV101201128; called by muse, mutect2, varscan2
- ABCA7 | c.4690C>T p.R1564* | Nonsense Mutation (SNP) | VAF 28/78 reads (36%) | catalogued as rs774258082, CM157219; called by muse, mutect2, varscan2
- ABCA7 | c.5855C>T p.P1952L | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM157261; called by muse, mutect2, varscan2
- ABCA8 | c.4091C>T p.A1364V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as rs200857969, COSV52199286; called by muse, mutect2, varscan2
- ABCA8 | c.2236G>A p.V746I | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs1322510127; called by muse, mutect2, varscan2
- ABCA8 | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs763479264, COSV52209939; called by muse, mutect2, varscan2
- ABCB4 | c.3174G>T p.E1058D | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV55942233; called by muse, varscan2
- ABCB4 | c.2870G>A p.R957Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.392); catalogued as COSV55936843; called by muse, varscan2
- ABCB4 | c.2124G>A p.W708* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV55941044; called by muse, mutect2, varscan2
- ABCB4 | c.1886A>G p.N629S | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs77961715; called by muse, varscan2
- ABCB6 | c.2261C>T p.T754M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs61733626; called by muse, mutect2, varscan2
- ABCC1 | c.3485T>G p.V1162G | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100580268; called by muse, mutect2, varscan2
- ABCC1 | c.4033G>A p.E1345K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs924222774; called by muse, mutect2, varscan2
- ABCC11 | c.4076C>T p.P1359L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745638318; called by muse, mutect2, varscan2
- ABCC11 | c.3881G>A p.R1294H | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs774156655, COSV62323560; called by muse, mutect2, varscan2
- ABCC11 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs781263618, COSV62322754; called by muse, mutect2, varscan2
- ABCC12 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100252513; called by muse, varscan2
- ABCC3 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.628); catalogued as rs200070901; called by muse, mutect2, varscan2
- ABCC5 | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs376038853; called by muse, mutect2, varscan2
- ABCC6 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.224); catalogued as rs776248626, COSV52742326; called by muse, mutect2, varscan2
- ABCC6 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs1330645129; called by muse, mutect2, varscan2
- ABCC9 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs373792254; called by muse, mutect2, varscan2
- ABCD3 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100931411; called by muse, mutect2, varscan2
- ABCG1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs959974308, COSV59209161; called by muse, mutect2, varscan2
- ABCG2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs767893166, COSV52947919; called by muse, varscan2
- ABCG5 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201552973; called by muse, mutect2, varscan2
- ABCG5 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1404472996; called by muse, mutect2, varscan2
- ABCG8 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs758668360, COSV55393995; called by muse, mutect2, varscan2
- ABCG8 | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374361804, COSV99699448; called by muse, mutect2, varscan2
- ABHD16A | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1306314144; called by muse, mutect2, varscan2
- ABHD16B | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs557793337; called by muse, varscan2
- ABHD17A | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.255); catalogued as rs536953984; called by muse, mutect2
- ABHD3 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs1288515872; called by muse, mutect2, varscan2
- ABHD4 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as rs748032634, COSV99360449; called by mutect2, varscan2
- ABL1 | c.2941G>A p.V981I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.052); catalogued as rs769473644, COSV59332487; called by muse, varscan2
- ABLIM1 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs772367802, COSV53310808; called by muse, mutect2, varscan2
- ABLIM2 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1184643633, COSV104405464; called by muse, mutect2, varscan2
- ABR | c.2021G>A p.R674K (on ENST00000302538 / NM_021962.5; = p.R637K on NM_001092.5) | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as rs1035244499; called by muse, mutect2, varscan2
- ABR | c.896C>T p.T299M (on ENST00000302538 / NM_021962.5; = p.T262M on NM_001092.5) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.39); catalogued as COSV52141498; called by muse, mutect2, varscan2
- ABRAXAS2 | c.76G>T p.G26* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | catalogued as COSV53718441; called by muse, mutect2, varscan2
- ABT1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.91); catalogued as rs782010945, COSV51292132; called by muse, mutect2, varscan2
- ABTB1 | c.1272G>T p.E424D (on ENST00000232744 / NM_172027.3; = p.E282D on NM_032548.3) | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99230228; called by muse, mutect2, varscan2
- ABTB2 | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377195382; called by muse, mutect2, varscan2
- AC004593.2 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs950872576, COSV56087851; called by muse, mutect2, varscan2
- AC005324.2 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); catalogued as rs1211508499; called by muse, mutect2, varscan2
- AC006059.2 | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59606331; called by muse, varscan2
- AC006059.2 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | catalogued as rs753473480, COSV59605827; called by muse, varscan2
- AC068580.4 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.046); catalogued as rs371522391, COSV52588844; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC092143.1 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1419813994; called by muse, mutect2, varscan2
- AC098582.1 | c.1208A>G p.N403S | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.101); catalogued as rs768549121; called by muse, mutect2, varscan2
- ACACA | c.4927C>T p.R1643W | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304734471; called by muse, mutect2, varscan2
- ACACB | c.4756C>T p.R1586C | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752226105, COSV58147388; called by muse, mutect2, varscan2
- ACAD10 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1279452264; called by muse, mutect2, varscan2
- ACAD10 | c.2273C>T p.A758V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as rs545041174; called by muse, varscan2
- ACAD8 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs373557720; called by muse, mutect2, varscan2
- ACADVL | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as rs192904909; called by muse, mutect2, varscan2
- ACAP3 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100686262; called by muse, mutect2, varscan2
- ACBD7 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs371874832; called by mutect2, varscan2
- ACE | c.3607C>T p.P1203S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99326202; called by muse, mutect2, varscan2
- ACE2 | c.2302C>T p.R768W | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs140016715, COSV53024501; called by muse, mutect2, varscan2
- ACIN1 | c.3703G>A p.V1235I | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs1273300535; called by muse, mutect2, varscan2
- ACIN1 | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as rs980819079; called by muse, mutect2, varscan2
- ACIN1 | c.1381A>G p.T461A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52976807; called by muse, varscan2
- ACLY | c.3254G>A p.R1085H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59862485; called by muse, mutect2, varscan2
- ACLY | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as rs369798437; called by muse, mutect2, varscan2
- ACO2 | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV53442932; called by muse, mutect2, varscan2
- ACOT11 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs776686227, COSV56363969; called by muse, mutect2, varscan2
- ACOT7 | c.523G>A p.E175K (on ENST00000377855 / NM_181864.3; = p.E165K on NM_007274.4) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs1344456977, COSV64113680; called by muse, mutect2, varscan2
- ACOT8 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 21/66 reads (32%) | catalogued as rs758520030, COSV54168533; called by muse, mutect2, varscan2
- ACOX1 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs767935600; called by muse, mutect2, varscan2
- ACOX3 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs760846643; called by muse, mutect2, varscan2
- ACOXL | c.1570C>T p.R524W (on ENST00000389811 / NM_001371254.1; = p.R494W on NM_001142807.4) | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs773104700, COSV67736418; called by muse, mutect2, varscan2
- ACP7 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs770475104; called by muse, mutect2, varscan2
- ACSBG1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs761047347, COSV99357019; called by muse, mutect2, varscan2
- ACSL1 | c.1735C>T p.R579* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as rs1160032491, COSV55662898; called by muse, mutect2, varscan2
- ACSL3 | c.1087A>G p.K363E | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62480729; called by muse, mutect2, varscan2
- ACSL4 | c.2129G>A p.G710D (on ENST00000340800 / NM_022977.2; = p.G669D on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.698); catalogued as rs766299247; called by muse, mutect2, varscan2
- ACSL5 | c.1615G>A p.D539N (on ENST00000354273; = p.D595N on NM_016234.3) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs749931911, COSV61130657; called by muse, varscan2
- ACSM1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs149435984, COSV54639837; called by muse, mutect2, varscan2
- ACSM1 | c.1470G>T p.E490D | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV99533023; called by muse, mutect2, varscan2
- ACSM6 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58980875; called by muse, mutect2, varscan2
- ACSS3 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs772788931, COSV54083770; called by muse, mutect2, varscan2
- ACTA1 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as COSV64203951; called by muse, varscan2
- ACTG1 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs1555667250; called by muse, mutect2, varscan2
- ACTN1 | c.2381G>A p.R794H | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs745580045; called by muse, mutect2, varscan2
- ACTN2 | c.2595G>T p.R865S | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV100856631; called by muse, varscan2
- ACTN3 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs374445358; called by muse, varscan2
- ACTN4 | c.2651C>T p.A884V | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs767861850; called by muse, varscan2
- ACTN4 | c.2672C>T p.A891V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99400780; called by muse, varscan2
- ACTR10 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs554639681, COSV54298006; called by muse, mutect2, varscan2
- ACTR1A | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99057023; called by muse, mutect2
- ACTRT3 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs776125776, COSV100377511; called by muse, mutect2, varscan2
- ACVRL1 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs971966438, CD140302, CX045361; called by muse, mutect2, varscan2
- ADAM15 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332319993; called by muse, mutect2
- ADAM18 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs765835846, COSV55844299; called by muse, mutect2, varscan2
- ADAM2 | c.1213-1G>T p.X405_splice | Splice Site (SNP) | VAF 18/34 reads (53%) | catalogued as COSV55860437; called by muse, mutect2, varscan2
- ADAM22 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs1291670982; called by muse, mutect2
- ADAM32 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs567675296, COSV65946823; called by muse, mutect2, varscan2
- ADAM8 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs376289867, COSV69865127; called by muse, varscan2
- ADAM8 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.175); catalogued as rs577506348; called by muse, mutect2, varscan2
- ADAMTS1 | c.1417C>T p.L473F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs769053235; called by muse, mutect2, varscan2
- ADAMTS12 | c.3788C>T p.T1263M | Missense Mutation (SNP) | VAF 101/224 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs757177041, COSV100710420, COSV61263698; called by muse, mutect2, varscan2
- ADAMTS12 | c.2717G>A p.R906Q | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775660919, COSV61259614; called by muse, varscan2
- ADAMTS13 | c.3107C>T p.S1036L | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs142607772, CM100615; called by muse, mutect2, varscan2
- ADAMTS13 | c.3224G>A p.R1075H | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs138770906; called by muse, mutect2, varscan2
- ADAMTS14 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs374197954; called by muse, mutect2, varscan2
- ADAMTS17 | c.2339A>G p.Y780C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51473426, COSV51478761; called by muse, mutect2, varscan2
- ADAMTS18 | c.2152G>A p.G718R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774517919; called by muse, varscan2
- ADAMTS18 | c.777A>C p.K259N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV51402914; called by muse, mutect2, varscan2
- ADAMTS18 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs763323193; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS20 | c.5239T>C p.Y1747H | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV67130031; called by muse, mutect2, varscan2
- ADAMTS3 | c.1247G>T p.G416V | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1560470876; called by muse, mutect2, varscan2
- ADAMTS3 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767858822, COSV54395960, COSV54401256; called by muse, mutect2, varscan2
- ADAMTS4 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs139714128; called by muse, mutect2, varscan2
- ADAMTS5 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.71); catalogued as rs748491619, COSV53177561; called by muse, varscan2
- ADAMTS7 | c.4903+1G>A p.X1635_splice | Splice Site (SNP) | VAF 44/113 reads (39%) | catalogued as rs747201167; called by muse, varscan2
- ADAMTS9 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs148570059; called by muse, varscan2
- ADAMTSL1 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs200648653, COSV99442517; called by muse, mutect2, varscan2
- ADAMTSL2 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 36/113 reads (32%) | catalogued as COSV100619027; called by muse, mutect2, varscan2
- ADAMTSL3 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54443016, COSV99720411; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138562816; called by muse, mutect2, varscan2
- ADAMTSL4 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.92); catalogued as rs199599791, COSV55010010; called by muse, varscan2
- ADAMTSL4 | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs375355414, COSV54996602; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs751676813, COSV54998967; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs778152887; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2951G>A p.R984H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs200667760; called by muse, varscan2
- ADAMTSL4 | c.3019C>T p.R1007* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as rs768395332; called by muse, varscan2
- ADARB1 | c.610G>T p.G204W | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as COSV62345844; called by muse, mutect2
- ADCK1 | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53080062; called by muse, mutect2, varscan2
- ADCK5 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs544823046; called by muse, mutect2, varscan2
- ADCY10 | c.3793G>A p.A1265T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV100896575; called by muse, mutect2, varscan2
- ADCY10 | c.2863C>T p.R955C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.791); catalogued as rs1388091820, COSV63244738; called by muse, mutect2, varscan2
- ADCY2 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781137779, COSV57868798, COSV57902234; called by muse, mutect2, varscan2
- ADCY3 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs772293701, COSV53172390; called by muse, mutect2, varscan2
- ADCY4 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs756925041, COSV60251947; called by muse, mutect2, varscan2
- ADCY5 | c.3343C>T p.R1115W | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs769892406; called by muse, mutect2, varscan2
- ADCY5 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59193338; called by muse, mutect2, varscan2
- ADCY5 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs777588020, COSV71901428; called by muse, mutect2, varscan2
- ADCY6 | c.3037G>A p.A1013T | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs561692050, COSV57169969; called by muse, mutect2, varscan2
- ADCY6 | c.2096G>A p.G699E | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV100327022; called by muse, mutect2, varscan2
- ADCY6 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs779226545; called by muse, mutect2, varscan2
- ADCY8 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs773742788, COSV53896347; called by muse, varscan2
- ADCY9 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs150452337; called by muse, varscan2
- ADCYAP1R1 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1321839365, COSV100416412, COSV58443767; called by muse, mutect2, varscan2
- ADD1 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.72); catalogued as rs1344117422; called by muse, mutect2
- ADD1 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750443352; called by muse, varscan2
- ADGRA1 | c.498G>A p.A166= | Splice Region (SNP) | VAF 13/34 reads (38%) | catalogued as rs767061322; called by muse, mutect2, varscan2
- ADGRA3 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1165791849, COSV51563231; called by muse, mutect2, varscan2
- ADGRB3 | c.2398G>A p.D800N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.27); catalogued as rs754848273, COSV65395147, COSV65421513; called by muse, mutect2, varscan2
- ADGRD1 | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.112); catalogued as rs766201065; called by muse, mutect2, varscan2
- ADGRE1 | c.514+1G>A p.X172_splice | Splice Site (SNP) | VAF 17/50 reads (34%) | catalogued as COSV99165280; called by muse, mutect2, varscan2
- ADGRE1 | c.1334G>A p.S445N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1440264128; called by muse, mutect2, varscan2
- ADGRE2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs200783500; called by muse, mutect2, varscan2
- ADGRE5 | c.1531G>A p.E511K (on ENST00000242786 / NM_078481.4; = p.E418K on NM_001784.5) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.078); catalogued as rs748373111, COSV54391440; called by muse, mutect2, varscan2
- ADGRF1 | c.2062C>T p.L688F | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs1427363317; called by muse, mutect2, varscan2
- ADGRF1 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV99347675; called by muse, mutect2
- ADGRF1 | c.1331G>A p.G444D | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs200594299; called by muse, mutect2, varscan2
- ADGRF5 | c.2264G>T p.S755I | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.758); catalogued as rs1039345740; called by muse, mutect2, varscan2
- ADGRF5 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as rs754867365, COSV51940699; called by muse, mutect2, varscan2
- ADGRG1 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1244227952; called by muse, mutect2, varscan2
- ADGRG4 | c.6440T>C p.L2147P | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as rs763229766; called by muse, mutect2, varscan2
- ADGRG4 | c.6854C>A p.S2285Y | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV99795602; called by muse, mutect2, varscan2
- ADGRG4 | c.9090G>T p.K3030N | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as COSV54963432, COSV99794228; called by muse, mutect2, varscan2
- ADGRL2 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as rs1487870704, COSV54650244, COSV99587694; called by muse, mutect2, varscan2
- ADGRL2 | c.1400G>T p.R467I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as COSV54655136, COSV54656571; called by muse, varscan2
- ADGRL2 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs771653946; called by muse, varscan2
- ADGRL2 | c.2398G>A p.G800R (on ENST00000370717 / NM_001366005.1; = p.G787R on NM_012302.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1216545723; called by muse, varscan2
- ADGRL3 | c.3619C>T p.R1207* (on ENST00000506720 / NM_001322402.2; = p.R1139* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as COSV72230574; called by muse, mutect2, varscan2
- ADGRL4 | c.1593G>T p.K531N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs200091440, COSV66062452; called by muse, mutect2, varscan2
- ADGRV1 | c.4117G>A p.A1373T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); catalogued as rs1226822421; called by muse, mutect2, varscan2
- ADGRV1 | c.6521T>C p.V2174A | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs368228246; called by muse, mutect2, varscan2
- ADIPOR1 | c.264G>A p.W88* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV100579674; called by muse, mutect2, varscan2
- ADIPOR1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1228660588, COSV61851852, COSV61852315; called by muse, mutect2, varscan2
- ADIPOR2 | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs145541863; called by muse, mutect2, varscan2
- ADM | c.530dup p.S178Efs*19 | Frame Shift Ins (INS) | VAF 28/60 reads (47%) | catalogued as rs773405081; called by mutect2, varscan2
- ADNP2 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs1369315320, COSV51538952; called by muse, mutect2, varscan2
- ADORA1 | c.222G>T p.Q74H | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs201501886; called by muse, mutect2, varscan2
- ADORA1 | c.555C>A p.F185L | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV55141209; called by muse, mutect2, varscan2
- ADORA2A | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.352); catalogued as rs769621641, COSV58380248; called by muse, varscan2
- ADPRH | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs895537782, COSV100813384; called by muse, mutect2, varscan2
- ADPRHL1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs139955911; called by muse, mutect2, varscan2
- ADRA1B | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.545); catalogued as rs761297353, COSV60701364; called by muse, mutect2
- ADRA2A | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54526656; called by muse, mutect2, varscan2
- ADRM1 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs1248219132, COSV53370852; called by muse, mutect2, varscan2
- AEN | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs144659811; called by muse, varscan2
- AFAP1 | c.2185G>A p.G729R | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1407197582; called by muse, mutect2, varscan2
- AFDN | c.2320C>T p.R774* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as rs750660726, COSV60045383; called by muse, mutect2, varscan2
- AFDN | c.3190C>T p.R1064* | Nonsense Mutation (SNP) | VAF 41/70 reads (59%) | catalogued as rs1245165524; called by muse, mutect2, varscan2
- AFG3L2 | c.1532C>A p.S511Y | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV99302140; called by muse, mutect2, varscan2
- AFTPH | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.911); catalogued as rs770856732; called by muse, varscan2
- AGA | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs761804469, COSV52807004; called by muse, mutect2, varscan2
- AGAP3 | c.2288G>A p.R763Q (on ENST00000622464; = p.R799Q on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.486); catalogued as rs777375076; called by muse, mutect2, varscan2
- AGAP4 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1327009720, COSV71164763; called by mutect2, varscan2
- AGBL1 | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs776681505, COSV66856002; called by muse, mutect2, varscan2
- AGER | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.432); catalogued as rs367834402; called by muse, mutect2, varscan2
- AGPAT5 | c.721C>T p.R241* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as rs1563304318; called by muse, mutect2, varscan2
- AGPS | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as rs1372190083, COSV51561302; called by muse, mutect2, varscan2
- AGR2 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs923936131, COSV101290819; called by muse, varscan2
- AGTR1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200184769, COSV62557211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHDC1 | c.2233C>T p.R745W | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99899869; called by muse, mutect2, varscan2
- AHI1 | c.3191C>T p.A1064V | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769705227, COSV55637817; called by muse, mutect2, varscan2
- AHI1 | c.818C>A p.S273Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV99663659; called by muse, mutect2, varscan2
- AHNAK | c.15383C>T p.A5128V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as rs1266483225; called by muse, mutect2, varscan2
- AHNAK | c.9151C>A p.L3051I | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1020256590, COSV99948108; called by muse, mutect2, varscan2
- AHNAK | c.3424G>A p.E1142K | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs372994724; called by muse, mutect2, varscan2
- AHNAK | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs747760505, COSV57203064; called by muse, mutect2, varscan2
- AHNAK2 | c.16035G>T p.E5345D | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.724); catalogued as COSV100316795; called by muse, mutect2, varscan2
- AHNAK2 | c.12680C>T p.P4227L | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1196408540; called by muse, mutect2, varscan2
- AHR | c.2309C>T p.S770L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs1343738113; called by muse, mutect2, varscan2
- AHRR | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs533137778; called by muse, mutect2, varscan2
- AIMP2 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.402); catalogued as rs1310790068; called by muse, mutect2, varscan2
- AIRE | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as COSV99381602; called by muse, mutect2, varscan2
- AJM1 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.528); catalogued as rs747373398; called by muse, varscan2
- AK9 | c.5432C>A p.S1811Y | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV101413984; called by muse, mutect2, varscan2
- AKAP1 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756066356, COSV61807142; called by muse, mutect2, varscan2
- AKAP1 | c.2503G>A p.D835N | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs1269592958, COSV61805535; called by muse, mutect2, varscan2
- AKAP14 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1210211627; called by muse, mutect2, varscan2
- AKAP17A | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.022); catalogued as rs367544429; called by muse, mutect2, varscan2
- AKAP4 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.817); catalogued as rs782377975, COSV62074933; called by muse, mutect2, varscan2
- AKAP6 | c.3001C>T p.R1001* | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as rs1224370847; called by muse, mutect2, varscan2
- AKAP8 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs547463044; called by muse, mutect2, varscan2
- AKR1A1 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1489844519, COSV61087998; called by muse, mutect2, varscan2
- AKR1B10 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs774817445, COSV62055101; called by muse, mutect2
- AKR1C2 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs782021111; called by muse, mutect2, varscan2
- AKR1C2 | c.369+1G>A p.X123_splice | Splice Site (SNP) | VAF 42/106 reads (40%) | catalogued as rs1330231454; called by muse, mutect2, varscan2
- AKR1C4 | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554796766; called by muse, mutect2, varscan2
- AKR1C4 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as rs782309814, CM151169, COSV99578573; called by muse, mutect2, varscan2
- AKR1E2 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs773986145; called by muse, varscan2
- AKR7A3 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64389743; called by muse, mutect2, varscan2
- AKT2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as rs1485745630, COSV60909229, COSV60909859; called by muse, mutect2, varscan2
- AL049569.3 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 40/84 reads (48%) | catalogued as rs369906056; called by muse, mutect2, varscan2
- AL121899.2 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368238578; called by muse, mutect2, varscan2
- AL136295.1 | c.2297G>A p.R766H | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55782086; called by muse, mutect2, varscan2
- AL136295.1 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.905); catalogued as rs762779266, COSV55778177; called by muse, mutect2, varscan2
- ALAS1 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs144316660; called by muse, mutect2, varscan2
- ALB | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs72552709, CM910023, COSV99890657; ClinVar: other; called by muse, mutect2, varscan2
- ALDH16A1 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | catalogued as rs534259783; called by muse, varscan2
- ALDH16A1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs756830979, COSV53194076; called by muse, mutect2
- ALDH18A1 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762588270; called by muse, mutect2, varscan2
- ALDH1B1 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs575584464; called by muse, varscan2
- ALDH1L2 | c.2146-1G>A p.X716_splice | Splice Site (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99311359; called by muse, varscan2
- ALDH2 | c.1459A>G p.M487V | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs1223518213; called by muse, mutect2, varscan2
- ALDH3A2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1363743696; called by muse, mutect2, varscan2
- ALDH7A1 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs958089083; called by muse, mutect2, varscan2
- ALG1 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as rs762783729, COSV52159196; called by muse, mutect2, varscan2
- ALG12 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 22/40 reads (55%) | PolyPhen benign (0.094); catalogued as rs746493927; called by muse, varscan2
- ALG13 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | catalogued as COSV52644790; called by muse, varscan2
- ALG13 | c.2395C>T p.R799C | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs763877039, COSV52639820; called by muse, mutect2, varscan2
- ALG3 | c.764G>A p.S255N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as rs769011763; called by muse, varscan2
- ALKBH4 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754992172; called by muse, mutect2, varscan2
- ALMS1 | c.3356A>C p.E1119A | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV100044031; called by muse, mutect2, varscan2
- ALMS1 | c.4471C>T p.P1491S | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV52503353; called by muse, mutect2, varscan2
- ALMS1 | c.7033C>T p.R2345W | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs776611154; called by muse, varscan2
- ALMS1 | c.7433C>A p.S2478* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as CM1310238; called by muse, mutect2, varscan2
- ALOX15B | c.1357C>A p.L453I | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV66480302; called by muse, mutect2, varscan2
- ALOX5 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs923445285; called by muse, mutect2, varscan2
- ALOXE3 | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.954); catalogued as rs768352670, COSV59078051; called by muse, mutect2, varscan2
- ALOXE3 | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs1381168698; called by muse, mutect2
- ALPI | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761639198; called by muse, mutect2, varscan2
- ALPK2 | c.4501G>A p.G1501S | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.035); catalogued as rs748622515, COSV64490638; called by muse, mutect2, varscan2
- ALPL | c.119C>A p.A40D | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as CM980056; called by muse, mutect2, varscan2
- ALPL | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.161); catalogued as rs1212356217; called by muse, mutect2, varscan2
- ALX1 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as rs1432369243; called by muse, mutect2, varscan2
- ALX4 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.852); catalogued as rs1439142170; called by muse, mutect2, varscan2
- ALX4 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs104894197, CM060200, COSV61324798; called by muse, mutect2, varscan2
- AMFR | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs765477204; called by muse, mutect2, varscan2
- AMHR2 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs754059893, COSV57685283; called by muse, mutect2, varscan2
- AMIGO2 | c.1085C>A p.S362Y | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV104384698, COSV99873413; called by muse, mutect2, varscan2
- AMIGO3 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV57538407; called by muse, mutect2, varscan2
- AMOT | c.2875G>A p.V959I (on ENST00000371959 / NM_001113490.1; = p.V550I on NM_133265.3) | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs775245818; called by muse, mutect2, varscan2
- AMOTL1 | c.1659C>A p.F553L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs866769079, COSV58565783, COSV58567541; called by muse, mutect2, varscan2
- AMPD2 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as rs150197784, COSV99857818; called by muse, varscan2
- AMPD2 | c.1540G>A p.V514M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.938); catalogued as rs1383175083, COSV56650973; called by mutect2, varscan2
- AMPD2 | c.2447C>T p.A816V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1477098445; called by muse, mutect2, varscan2
- AMPH | c.1547C>A p.T516N | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV57732702; called by muse, mutect2, varscan2
- AMTN | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1335272912; called by muse, mutect2, varscan2
- AMY1A | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.929); catalogued as rs536477630; called by mutect2, varscan2
- AMY2A | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201672724; called by mutect2, varscan2
- AMZ1 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs371188824; called by muse, mutect2, varscan2
- ANAPC1 | c.4232G>A p.R1411Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1267982576; called by mutect2, varscan2
- ANAPC10 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV58738725; called by muse, mutect2, varscan2
- ANAPC2 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs777263918, COSV60572162; called by muse, mutect2, varscan2
- ANAPC2 | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs149286860; called by muse, mutect2, varscan2
- ANAPC4 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.065); catalogued as rs377456652; called by muse, mutect2, varscan2
- ANAPC5 | c.1349G>A p.S450N | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.963); catalogued as rs1555272364; called by muse, mutect2, varscan2
- ANGPTL4 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1384396557; called by muse, mutect2, varscan2
- ANK1 | c.2888C>T p.P963L | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1426799357; called by muse, mutect2
- ANK2 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.045); catalogued as rs869025359; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.6082C>T p.R2028W | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1411026310, COSV52150851; called by muse, mutect2, varscan2
- ANK2 | c.6940G>T p.G2314C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as COSV52161652; called by muse, mutect2, varscan2
- ANK2 | c.9587C>T p.S3196L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.254); catalogued as rs144719173, COSV52190287; called by muse, mutect2
- ANK2 | c.10804C>T p.R3602* | Nonsense Mutation (SNP) | VAF 30/59 reads (51%) | catalogued as COSV52152721; called by muse, mutect2, varscan2
- ANK3 | c.12487C>T p.R4163* (on ENST00000280772 / NM_001320874.2; = p.R684* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as COSV55058581; called by muse, mutect2, varscan2
- ANKAR | c.3476G>A p.R1159H | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs752651499, COSV55619409; called by muse, mutect2, varscan2
- ANKAR | c.4238G>A p.R1413K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs1336238891; called by muse, mutect2, varscan2
- ANKEF1 | c.2168G>A p.R723Q | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs201768005, COSV65692226; called by muse, mutect2, varscan2
- ANKFN1 | c.585G>T p.R195S | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV59451146; called by muse, mutect2, varscan2
- ANKLE1 | c.1621G>A p.V541M (on ENST00000394458; = p.V487M on NM_152363.6) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485452664; called by muse, mutect2, varscan2
- ANKRD1 | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV63311157; called by muse, mutect2, varscan2
- ANKRD11 | c.7564G>A p.E2522K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56366745; called by muse, mutect2, varscan2
- ANKRD11 | c.6373G>A p.A2125T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs764665666, COSV56359633; called by muse, varscan2
- ANKRD11 | c.3779C>T p.S1260L | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as COSV56372025; called by muse, mutect2, varscan2
- ANKRD11 | c.3442G>A p.G1148S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs143417087; called by muse, varscan2
- ANKRD13D | c.*910C>T | Splice Region (SNP) | VAF 31/65 reads (48%) | catalogued as rs769767794; called by muse, mutect2, varscan2
- ANKRD17 | c.7223C>T p.P2408L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as rs143868014, COSV100430057; called by muse, mutect2, varscan2
- ANKRD17 | c.7057G>A p.G2353R | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.159); catalogued as rs139173196; called by muse, mutect2, varscan2
- ANKRD17 | c.5936C>T p.T1979M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.293); catalogued as rs755183443, COSV58221224; called by muse, mutect2, varscan2
- ANKRD20A2P | c.170G>A p.S57N | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.637); catalogued as rs1398164470; called by muse, mutect2, varscan2
- ANKRD27 | c.1330G>A p.V444I | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as rs746397621, COSV60131342, COSV60131463; called by muse, mutect2, varscan2
- ANKRD28 | c.2143C>T p.R715W | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs202220330; called by muse, mutect2, varscan2
- ANKRD30A | c.1654T>G p.F552V (on ENST00000611781; = p.F496V on NM_052997.2) | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.879); catalogued as COSV64603637; called by muse, mutect2, varscan2
- ANKRD35 | c.1912C>T p.R638W | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553739131, COSV62909438; called by muse, mutect2, varscan2
- ANKRD44 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs766285368; called by muse, mutect2, varscan2
- ANKRD46 | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.946); catalogued as rs1014683367; called by muse, varscan2
- ANKRD49 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as rs767511021, COSV57060117; called by muse, mutect2, varscan2
- ANKRD49 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs1361548385, COSV57059778; called by muse, mutect2
- ANKRD50 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV72385820; called by muse, mutect2, varscan2
- ANKRD52 | c.2656G>A p.A886T | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as rs766786981; called by muse, mutect2, varscan2
- ANKRD52 | c.2575C>T p.R859W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs538818712; called by muse, mutect2, varscan2
- ANKRD52 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.427); catalogued as rs775597003, COSV99921249; called by muse, mutect2, varscan2
- ANKRD53 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.79); catalogued as COSV99721212; called by muse, mutect2, varscan2
- ANKS1A | c.2479G>A p.A827T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs778083867; called by muse, mutect2, varscan2
- ANKS1B | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs1314803484; called by muse, mutect2, varscan2
- ANKZF1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs373512501; called by muse, varscan2
- ANLN | c.3196G>A p.E1066K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as COSV56076754; called by muse, mutect2, varscan2
- ANO1 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as rs752257777; called by muse, varscan2
- ANO10 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.781); catalogued as rs144272231, CM1411302; called by muse, varscan2
- ANO2 | c.536G>A p.G179E (on ENST00000356134 / NM_001278597.3; = p.G183E on NM_001278596.3) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59028169; called by muse, mutect2, varscan2
- ANO3 | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.13); catalogued as COSV56797563; called by muse, mutect2, varscan2
- ANO3 | c.2905C>T p.R969W | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs373975805; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO4 | c.2864C>T p.P955L (on ENST00000392977 / NM_001286615.2; = p.P920L on NM_178826.4) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1275058200, COSV54600642; called by muse, varscan2
- ANO6 | c.1611C>T p.F537= | Splice Region (SNP) | VAF 16/44 reads (36%) | catalogued as rs536008906, COSV57662793; called by muse, mutect2, varscan2
- ANO6 | c.2411C>T p.T804I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.246); catalogued as rs756730775; called by muse, mutect2, varscan2
- ANO7 | c.2024G>A p.R675H (on ENST00000274979; = p.R621H on NM_001370694.2) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs545708893, COSV51471794, COSV51475315; called by muse, mutect2, varscan2
- ANO8 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as rs1159002768; called by muse, mutect2, varscan2
- ANO9 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs940940079; called by muse, mutect2, varscan2
- ANOS1 | c.1100A>G p.D367G | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs1385966957; called by muse, mutect2, varscan2
- ANP32A | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV51189466; called by muse, mutect2, varscan2
- ANXA2 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as rs763951173, COSV60318286; called by muse, mutect2, varscan2
- ANXA2R | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as rs1393011200; called by muse, mutect2, varscan2
- ANXA6 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1233962893, COSV62908283; called by muse, mutect2, varscan2
- AOC3 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as rs139601722; called by muse, mutect2, varscan2
- AOX1 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV65979784; called by muse, mutect2, varscan2
- AP001781.2 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99499598; called by muse, mutect2, varscan2
- AP1AR | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as rs779198486; called by muse, mutect2, varscan2
- AP1S2 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV100236757; called by muse, mutect2, varscan2
- AP2A1 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.712); catalogued as rs779214091; called by muse, mutect2, varscan2
- AP2A2 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.887); catalogued as rs376073560; called by muse, mutect2, varscan2
- AP3B2 | c.1553T>G p.I518S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55614352; called by muse, mutect2, varscan2
- AP3D1 | c.3285C>T p.S1095= | Splice Region (SNP) | VAF 20/62 reads (32%) | catalogued as rs774547405; called by muse, varscan2
- AP3D1 | c.2801C>T p.T934I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as rs896475933; called by muse, mutect2, varscan2
- AP4M1 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs371712994; called by muse, mutect2, varscan2
- AP5Z1 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs754300113; called by muse, varscan2
- AP5Z1 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as rs751537911; called by muse, mutect2, varscan2
- APAF1 | c.1301G>A p.R434H (on ENST00000551964 / NM_181861.2; = p.R423H on NM_001160.3) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs201872620, COSV59661508; called by muse, mutect2, varscan2
- APBA1 | c.2359C>T p.R787W | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55226373; called by muse, mutect2, varscan2
- APBA2 | c.39G>A p.M13I | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs571580177; called by muse, mutect2, varscan2
- APCS | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 55/119 reads (46%) | catalogued as rs879661012, COSV54817191; called by muse, mutect2, varscan2
- APEH | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as rs577640330, COSV56517850; called by muse, mutect2, varscan2
- APEH | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs774564457; called by muse, mutect2, varscan2
- APEH | c.1837G>A p.V613M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769034633; called by muse, varscan2
- APEX2 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as COSV58193730; called by muse, mutect2, varscan2
- APH1A | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs71622685; called by muse, mutect2, varscan2
- APLP1 | c.1020G>T p.K340N | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV55701510; called by muse, mutect2, varscan2
- APOB | c.8111C>T p.A2704V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs201874707, COSV51930390, COSV51960377; ClinVar: uncertain significance; called by muse, varscan2
- APOBEC4 | c.759A>C p.K253N | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.42); PolyPhen benign (0.112); catalogued as rs775980223; called by muse, mutect2, varscan2
- APOBEC4 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as rs141963987; called by muse, mutect2
- APOO | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs369973145, COSV64870573; called by muse, mutect2, varscan2
- APPL2 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs149470075; called by muse, mutect2, varscan2
- AQP12A | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1401939125; called by mutect2, varscan2
- ARAF | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); catalogued as rs765492001; called by muse, mutect2, varscan2
- ARAF | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs200106543, COSV51692083; called by muse, mutect2, varscan2
- ARF1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.591); catalogued as COSV55254149; called by muse, varscan2
- ARF1 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1434233811; called by muse, varscan2
- ARF1 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55254451; called by muse, mutect2, varscan2
- ARFGEF3 | c.5825C>T p.S1942F | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.174); catalogued as COSV52457158; called by muse, mutect2, varscan2
- ARHGAP1 | c.595G>A p.V199M | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as rs568708140; called by muse, mutect2, varscan2
- ARHGAP12 | c.1620G>T p.K540N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60963006; called by muse, mutect2, varscan2
- ARHGAP17 | c.2546G>A p.R849H (on ENST00000289968 / NM_001006634.3; = p.R771H on NM_018054.6) | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.425); catalogued as rs760135610, COSV51512573, COSV99253191; called by muse, mutect2, varscan2
- ARHGAP20 | c.1873C>A p.L625I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs1046774323; called by muse, mutect2, varscan2
- ARHGAP22 | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as rs1347475923, COSV50937076; called by muse, varscan2
- ARHGAP22 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1231366282, COSV99984513; called by muse, mutect2, varscan2
- ARHGAP25 | c.1885G>A p.E629K (on ENST00000409202 / NM_001007231.3; = p.E621K on NM_014882.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV54901722; called by muse, mutect2, varscan2
- ARHGAP27 | c.2572G>A p.E858K (on ENST00000428638 / NM_001282290.1; = p.E517K on NM_199282.3) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1311789933; called by muse, varscan2
- ARHGAP28 | c.544C>T p.P182S (on ENST00000383472 / NM_001366230.1; = p.P23S on NM_001010000.3) | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1239125385; called by muse, mutect2, varscan2
- ARHGAP30 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV63516492; called by muse, mutect2, varscan2
- ARHGAP31 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as COSV51797933; called by muse, mutect2, varscan2
- ARHGAP31 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as rs886057800, COSV99957284; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP32 | c.5266C>T p.R1756W (on ENST00000310343 / NM_001378025.1; = p.R1407W on NM_014715.4) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs762590933, COSV59843548; called by muse, mutect2, varscan2
- ARHGAP35 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV101351306; called by muse, mutect2, varscan2
- ARHGAP35 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV68334058; called by muse, mutect2, varscan2
- ARHGAP36 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as rs866578619, COSV99357958; called by muse, mutect2, varscan2
- ARHGAP36 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.976); catalogued as rs766840004, COSV52266960; called by muse, mutect2, varscan2
- ARHGAP45 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs575124517; called by muse, varscan2
- ARHGAP5 | c.2335A>G p.R779G | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139895818; called by muse, mutect2
- ARHGAP6 | c.1652C>T p.S551F | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100272964; called by muse, mutect2, varscan2
- ARHGEF1 | c.2486G>A p.R829Q | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782226783, COSV61527748; called by muse, mutect2, varscan2
- ARHGEF10L | c.1942G>A p.G648S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs991517738; called by muse, varscan2
- ARHGEF11 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs148414156; called by muse, varscan2
- ARHGEF15 | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV62724424; called by muse, mutect2, varscan2
- ARHGEF16 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs559918389, COSV65681685; called by muse, mutect2, varscan2
- ARHGEF17 | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs373537661; called by muse, varscan2
- ARHGEF18 | c.350C>T p.P117L (on ENST00000359920 / NM_001130955.2; = p.P13L on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs751248837; ClinVar: uncertain significance; called by muse, mutect2
- ARHGEF18 | c.505G>A p.A169T (on ENST00000359920 / NM_001130955.2; = p.A65T on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs760864454; called by muse, mutect2, varscan2
- ARHGEF2 | c.1322G>A p.R441H (on ENST00000361247 / NM_001162383.2; = p.R413H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs752620262, COSV58116702; called by muse, varscan2
- ARHGEF3 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430716980, COSV99576082; called by muse, mutect2, varscan2
- ARHGEF3 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV56326073; called by muse, mutect2, varscan2
- ARHGEF3 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs368331403; called by muse, mutect2, varscan2
- ARHGEF37 | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1424688618; called by muse, mutect2, varscan2
- ARHGEF38 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1399479305; called by muse, mutect2, varscan2
- ARHGEF4 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV58125158; called by muse, mutect2, varscan2
- ARHGEF4 | c.1786C>T p.R596C | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs376557347; called by muse, mutect2
- ARHGEF4 | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767872391; called by muse, mutect2, varscan2
- ARHGEF7 | c.1556G>T p.G519V (on ENST00000375741 / NM_001113511.2; = p.G341V on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99521079; called by muse, mutect2, varscan2
- ARHGEF9 | c.407G>T p.R136I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53636625; called by muse, varscan2
- ARID1A | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100250607, COSV61371935; called by muse, mutect2, varscan2
- ARID1B | c.4781C>T p.T1594I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.737); catalogued as CX1314077, COSV99268955; called by muse, mutect2, varscan2
- ARID3A | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as rs772606131; called by muse, varscan2
- ARID3B | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100654534, COSV100654733; called by muse, mutect2, varscan2
- ARID4A | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as rs773999866, COSV62165000; called by muse, mutect2, varscan2
- ARID4A | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as COSV62166811; called by muse, mutect2, varscan2
- ARID4B | c.3788G>A p.R1263H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs374588299; called by muse, mutect2, varscan2
- ARID5B | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs550591609, COSV99688722; called by muse, mutect2, varscan2
- ARID5B | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs747413904, COSV54421305; called by muse, mutect2, varscan2
- ARID5B | c.1295A>C p.N432T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV54414653; called by muse, mutect2, varscan2
- ARL14EP | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as rs777607290, COSV56342326; called by muse, varscan2
- ARL5B | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 23/45 reads (51%) | catalogued as COSV66011148; called by muse, mutect2, varscan2
- ARL5B | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs372696681; called by muse, mutect2, varscan2
- ARL6IP1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV58614402; called by muse, mutect2, varscan2
- ARL8A | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 32/65 reads (49%) | catalogued as COSV99693293; called by muse, mutect2, varscan2
- ARMC3 | c.2423G>T p.R808I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV53062958; called by muse, mutect2, varscan2
- ARMC5 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51658619; called by muse, mutect2, varscan2
- ARMC8 | c.1652C>T p.T551I (on ENST00000469044 / NM_001363941.2; = p.T537I on NM_015396.6) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.137); catalogued as COSV58619175; called by muse, mutect2, varscan2
- ARMCX2 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs201060387; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs369432744, COSV100771865, COSV63438046; called by muse, mutect2, varscan2
- ARNT | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); catalogued as rs112213997; called by muse, mutect2, varscan2
- ARNT2 | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs745717006, COSV100309617; called by muse, mutect2, varscan2
- ARNT2 | c.1011C>A p.F337L | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV57583529; called by muse, mutect2, varscan2
- ARPC1B | c.707+1G>A p.X236_splice | Splice Site (SNP) | VAF 20/54 reads (37%) | catalogued as COSV53163433; called by muse, mutect2, varscan2
- ARRB1 | c.407C>T p.T136M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs748274343; called by muse, mutect2, varscan2
- ARRDC1 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763619287; called by muse, varscan2
- ARRDC1 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.786); catalogued as rs201795480, COSV65060234, COSV65060321; called by muse, varscan2
- ARRDC2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs540013259, COSV99717020; called by muse, varscan2
- ARRDC3 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99475229, COSV99475257; called by muse, mutect2, varscan2
- ARRDC4 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs767572683; called by muse, mutect2, varscan2
- ARSI | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.92); catalogued as rs1235311214, COSV100155910; called by muse, mutect2, varscan2
- ARSK | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147168858; called by muse, mutect2, varscan2
- ARSK | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.136); catalogued as rs763396857, COSV66169295; called by muse, mutect2, varscan2
- ARSL | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 49/91 reads (54%) | catalogued as rs1335931206, CM030776; called by muse, mutect2, varscan2
- ARSL | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs140499958; called by muse, mutect2, varscan2
- ARVCF | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs200353808; called by muse, varscan2
- ASAH2 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 114/341 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272785683; called by muse, mutect2, varscan2
- ASAH2 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753831322, COSV100269971; called by muse, mutect2, varscan2
- ASAP2 | c.1381G>A p.G461R | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111321820; called by muse, mutect2, varscan2
- ASAP2 | c.2363C>A p.P788H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV99855572; called by muse, mutect2, varscan2
- ASAP3 | c.1765G>A p.V589I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs150324380; called by muse, varscan2
- ASB1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.963); catalogued as rs760949441, COSV52826260; called by muse, mutect2, varscan2
- ASB11 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.376); catalogued as rs199598614, COSV60355931; called by muse, mutect2, varscan2
- ASB15 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760024428; called by muse, varscan2
- ASB16 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs764652045; called by muse, varscan2
- ASB8 | c.836C>A p.S279Y | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.601); catalogued as COSV100402282; called by muse, varscan2
- ASB8 | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as rs771662561; called by muse, mutect2, varscan2
- ASCC2 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779333751; called by muse, mutect2, varscan2
- ASCC3 | c.6409C>T p.R2137* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as rs760927168, COSV64973923, COSV64977816; called by muse, mutect2, varscan2
- ASH2L | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs745887695; called by muse, mutect2, varscan2
- ASH2L | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1342895894, COSV51698982; called by muse, mutect2, varscan2
- ASH2L | c.1787A>G p.D596G | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs921116215; called by muse, mutect2, varscan2
- ASIC1 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1565732360, COSV57318193; called by muse, mutect2, varscan2
- ASIC3 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142655334; called by muse, mutect2, varscan2
- ASIC4 | c.1176G>T p.E392D (on ENST00000347842 / NM_182847.3; = p.E411D on NM_018674.6) | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.085); catalogued as COSV61733318; called by muse, mutect2, varscan2
- ASL | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs752397242, CM072868, COSV100509033; called by muse, varscan2
- ASMT | c.562+1G>A p.X188_splice | Splice Site (SNP) | VAF 78/186 reads (42%) | catalogued as rs1346859452; called by muse, mutect2, varscan2
- ASPG | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs761416472; called by muse, varscan2
- ASPH | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV101064580; called by muse, mutect2, varscan2
- ASPH | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.563); catalogued as rs772711048; called by muse, mutect2, varscan2
- ASPHD1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV58098535; called by muse, mutect2, varscan2
- ASPHD2 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780604426, COSV53217925; called by muse, varscan2
- ASPM | c.10269G>T p.K3423N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV104399271; called by muse, mutect2, varscan2
- ASPM | c.1080A>C p.E360D | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV54129959; called by muse, mutect2, varscan2
- ASPM | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs201143810, COSV54127897; called by muse, mutect2, varscan2
- ASTL | c.1265G>T p.R422I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV60903890; called by muse, mutect2
- ASTL | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs199510888, COSV60905260; called by muse, varscan2
- ASXL1 | c.3586G>A p.A1196T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as rs1339242781; called by muse, mutect2, varscan2
- ASXL2 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55453955, COSV55470068; called by muse, mutect2, varscan2
- ASXL3 | c.6589G>A p.V2197I | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.028); catalogued as rs778221486, COSV52476442; called by muse, mutect2, varscan2
- ATAD2B | c.3962C>T p.S1321L | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0.062); catalogued as rs765383233, COSV53196387; called by muse, mutect2, varscan2
- ATAD3B | c.477G>T p.K159N (on ENST00000308647; = p.K265N on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV58023437; called by muse, mutect2, varscan2
- ATF6B | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs758221215; called by muse, mutect2, varscan2
- ATF7 | c.1177C>T p.R393C (on ENST00000548446 / NM_001366555.2; = p.R382C on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748406956, COSV60645246; called by muse, mutect2, varscan2
- ATF7-NPFF | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as rs1250552308; called by muse, mutect2, varscan2
- ATF7IP2 | c.1463C>A p.S488Y | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61092963; called by muse, mutect2, varscan2
- ATG2A | c.5746C>T p.R1916C | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1432427091, COSV63475706; called by muse, mutect2, varscan2
- ATG2A | c.4634C>T p.T1545M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs977945889, COSV65969107; called by muse, mutect2, varscan2
- ATG3 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51926155; called by muse, varscan2
- ATG4A | c.122-1G>A p.X41_splice | Splice Site (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100619488; called by muse, mutect2, varscan2
- ATG4A | c.303G>A p.W101* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV58965873; called by muse, varscan2
- ATG4B | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1326302400; called by muse, varscan2
- ATG4D | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as rs376428796; called by muse, mutect2, varscan2
- ATG9A | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs746205802; called by muse, varscan2
- ATG9B | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 35/97 reads (36%) | catalogued as rs781445782, COSV65057582, COSV65059052; called by muse, mutect2, varscan2
- ATM | c.7291A>T p.K2431* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as CM035636; called by muse, mutect2, varscan2
- ATP10A | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs747360622, COSV63512971, COSV63522119; called by muse, mutect2, varscan2
- ATP10B | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as rs201139624, COSV100469476; called by muse, varscan2
- ATP11A | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371064768; called by muse, mutect2, varscan2
- ATP11A | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs372167641; called by muse, mutect2
- ATP11A | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); catalogued as COSV99370525; called by muse, mutect2, varscan2
- ATP11C | c.2524C>T p.R842C | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs185013366; called by muse, mutect2, varscan2
- ATP11C | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV59561009; called by muse, varscan2
- ATP11C | c.1569G>T p.M523I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV59572192; called by muse, mutect2, varscan2
- ATP12A | c.432+1G>A p.X144_splice | Splice Site (SNP) | VAF 17/56 reads (30%) | catalogued as rs766808530, COSV54513972; called by muse, mutect2, varscan2
- ATP12A | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs769933522, COSV54518384; called by muse, varscan2
- ATP13A1 | c.2677C>T p.R893* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as rs151089864; called by muse, varscan2
- ATP13A2 | c.2789C>T p.S930L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs778562581, COSV58700278; called by muse, mutect2, varscan2
- ATP13A3 | c.2097G>A p.W699* | Nonsense Mutation (SNP) | VAF 39/117 reads (33%) | catalogued as COSV99757194; called by muse, mutect2, varscan2
- ATP13A3 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs370845183; called by muse, mutect2, varscan2
- ATP13A5 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.166); catalogued as rs1170774281; called by muse, mutect2, varscan2
- ATP1A1 | c.2828C>T p.S943L | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55192266; called by muse, mutect2, varscan2
- ATP1A2 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as COSV63406099; called by muse, mutect2, varscan2
- ATP2A1 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.1); catalogued as rs751190054; called by muse, varscan2
- ATP2A2 | c.1963C>T p.R655W | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV100428818; called by muse, mutect2, varscan2
- ATP2A3 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs139726654; called by muse, varscan2
- ATP2B1 | c.3419C>T p.S1140L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53803716; called by muse, mutect2, varscan2
- ATP2B1 | c.1739C>A p.S580Y | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53811291; called by muse, mutect2, varscan2
- ATP2B1 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53813368; called by muse, mutect2, varscan2
- ATP2B2 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.697); catalogued as rs367841742; called by muse, mutect2, varscan2
- ATP2B3 | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1557013622; called by muse, mutect2, varscan2
- ATP2B4 | c.3335G>T p.S1112I | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV100398160; called by muse, mutect2, varscan2
- ATP2C1 | c.1893G>A p.S631= | Splice Region (SNP) | VAF 28/76 reads (37%) | catalogued as rs757607522; called by muse, varscan2
- ATP4A | c.15G>T p.E5D | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs758760854; called by muse, mutect2, varscan2
- ATP5F1C | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.524); catalogued as rs200847831, COSV100184265; called by muse, mutect2, varscan2
- ATP5MC2 | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 45/111 reads (41%) | catalogued as rs762053300, COSV100101012; called by muse, mutect2, varscan2
- ATP5MC3 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as rs1437202094, COSV99507117; called by muse, mutect2
- ATP6AP2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs138150013; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V0A2 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as rs368924297; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1438G>A p.G480S | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs1296470100, COSV57748785, COSV57750395; called by muse, mutect2, varscan2
- ATP6V0A4 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 35/115 reads (30%) | catalogued as rs756176052; called by muse, mutect2, varscan2
- ATP6V1A | c.1430C>T p.T477M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs752561873, COSV99850423; called by muse, varscan2
- ATP6V1B2 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs577956380, COSV99369247; called by muse, mutect2, varscan2
- ATP7A | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58451490; called by muse, mutect2, varscan2
- ATP8A1 | c.2192G>A p.G731D | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as rs1489645188; called by muse, mutect2
- ATP8A2 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs535509828, COSV54936164, COSV99680731; called by muse, mutect2, varscan2
- ATP8B2 | c.575G>A p.G192E (on ENST00000672630; = p.G159E on NM_001005855.2) | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV100528154; called by muse, mutect2, varscan2
- ATP8B2 | c.983A>G p.N328S (on ENST00000672630; = p.N295S on NM_001005855.2) | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.359); catalogued as rs1474437930; called by muse, mutect2, varscan2
- ATP9A | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.605); catalogued as rs1179222367; called by muse, mutect2, varscan2
- ATR | c.3601C>T p.R1201C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs974313531; called by muse, mutect2, varscan2
- ATRX | c.5771C>T p.S1924F | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV64878173; called by muse, mutect2, varscan2
- ATRX | c.3316G>A p.D1106N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.109); catalogued as COSV100970443; called by muse, varscan2
- ATRX | c.3003A>C p.K1001N | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs782295266, COSV64877278; called by muse, mutect2, varscan2
- ATRX | c.2418G>T p.K806N | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64882427; called by muse, varscan2
- ATXN2L | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs967231093, COSV57365447; called by muse, mutect2, varscan2
- ATXN7L2 | c.1942C>T p.R648W | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.482); catalogued as rs764064522; called by muse, mutect2, varscan2
- AURKB | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs879004728, COSV100298953; called by muse, mutect2, varscan2
- AUTS2 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs545795149; called by muse, mutect2, varscan2
- AUTS2 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs746226084; called by muse, varscan2
- AVPR1A | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100146832; called by muse, mutect2, varscan2
- AZI2 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV55423617; called by muse, mutect2, varscan2
- B2M | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs762924942, COSV62564948; called by muse, mutect2, varscan2
- B3GALT2 | c.686T>C p.I229T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as rs199956127; called by muse, mutect2, varscan2
- B3GLCT | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as rs770760169, COSV58456618; called by muse, mutect2, varscan2
- B3GNT4 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs765148419; called by muse, mutect2, varscan2
- B3GNT6 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs550987490; called by muse, mutect2, varscan2
- B3GNTL1 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142904836, COSV100302288; called by muse, mutect2, varscan2
- B4GALNT2 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs752552356, COSV55928493; called by muse, mutect2, varscan2
- B4GALT2 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs567524191; called by muse, mutect2, varscan2
- B4GALT6 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | catalogued as COSV52702410; called by muse, mutect2, varscan2
- B4GALT6 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV52702858; called by muse, mutect2, varscan2
- B4GAT1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs376475080; called by muse, varscan2
- BACE2 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1310970544, COSV57737531; called by muse, varscan2
- BACH1 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750785692, COSV54518596; called by muse, mutect2, varscan2
- BACH2 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.299); catalogued as rs751278336; called by muse, mutect2, varscan2
- BAG4 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs200494674, COSV54859728, COSV99781698; called by muse, mutect2, varscan2
- BAG4 | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779550882, COSV54861186; called by muse, mutect2, varscan2
- BAG6 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs774339536; called by muse, mutect2, varscan2
- BAHCC1 | c.4974C>A p.D1658E | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as rs1370473655; called by muse, mutect2, varscan2
- BAIAP3 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1042827145; called by muse, mutect2, varscan2
- BAIAP3 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as rs776493141, COSV60981215; called by muse, varscan2
- BAIAP3 | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.528); catalogued as rs762484237, COSV60977862; called by muse, mutect2, varscan2
- BAIAP3 | c.1879G>A p.V627I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs371042943; called by muse, varscan2
- BANK1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs777895274, COSV59842328; called by mutect2, varscan2
- BARD1 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV53619187; called by muse, mutect2, varscan2
- BARHL2 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs964944149, COSV64980851, COSV64981591; called by muse, mutect2, varscan2
- BAX | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0.05); catalogued as rs202190487, COSV53169117, COSV53170003; called by muse, mutect2, varscan2
- BAZ1A | c.4339C>T p.R1447* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as rs765397590; called by muse, varscan2
- BAZ1A | c.3446C>T p.A1149V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV62409629; called by mutect2, varscan2
- BAZ1A | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as rs750788363, COSV62409920; called by muse, mutect2, varscan2
- BAZ1B | c.4196G>A p.R1399H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs782235145; called by muse, mutect2, varscan2
- BAZ2B | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.968); catalogued as rs768136268; called by muse, varscan2
- BBS2 | c.959G>A p.G320D | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV99802929; called by muse, mutect2, varscan2
- BBS5 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV54751728; called by muse, mutect2, varscan2
- BBS7 | c.10A>G p.I4V | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs780400529; called by muse, mutect2, varscan2
- BBS9 | c.2449G>A p.D817N (on ENST00000242067 / NM_001348036.1; = p.D777N on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.311); catalogued as rs781476538, COSV54158031; called by muse, varscan2
- BBX | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs770138977, COSV57878573; called by muse, mutect2, varscan2
- BCAM | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as COSV54302412; called by muse, mutect2, varscan2
- BCAR1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs751023361; called by muse, varscan2
- BCAS3 | c.1921G>A p.D641N (on ENST00000390652 / NM_001353144.2; = p.D626N on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1306571781, COSV101176120; called by muse, mutect2, varscan2
- BCAT2 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60274120; called by muse, varscan2
- BCDIN3D | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs751096413, COSV100445470; called by muse, varscan2
- BCKDK | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1415332096; called by muse, mutect2, varscan2
- BCKDK | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs908554207, COSV99570578; called by muse, mutect2, varscan2
- BCKDK | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs553956491, COSV54893477; called by muse, mutect2, varscan2
- BCL11A | c.931C>T p.P311S (on ENST00000335712 / NM_001365609.1; = p.P345S on NM_018014.4) | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59623553; called by muse, mutect2, varscan2
- BCL2L12 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1443154833; called by muse, varscan2
- BCL2L12 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs1279410113; called by muse, varscan2
- BCL2L13 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs775247146; called by muse, varscan2
- BCL6 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs781532443, COSV51656438; called by muse, mutect2, varscan2
- BCL9 | c.3713G>A p.R1238H | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs371645881; called by muse, mutect2, varscan2
- BCLAF1 | c.1381C>A p.L461I | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs754912594; called by muse, mutect2, varscan2
- BCLAF1 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.558); catalogued as COSV100786866; called by muse, mutect2, varscan2
- BCLAF3 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.082); catalogued as rs373289111; called by muse, mutect2, varscan2
- BCO1 | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs761882293; called by muse, mutect2, varscan2
- BCOR | c.4540C>T p.R1514* (on ENST00000378444 / NM_001123385.2; = p.R1480* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as CM0910704, COSV60703956, COSV60716852; called by muse, mutect2, varscan2
- BCORL1 | c.3994C>T p.R1332* | Nonsense Mutation (SNP) | VAF 27/54 reads (50%) | catalogued as rs748288533, COSV54394595, COSV99499649; called by muse, mutect2, varscan2
- BEND2 | c.1983C>T p.S661= | Splice Region (SNP) | VAF 10/33 reads (30%) | catalogued as COSV66217275; called by muse, mutect2, varscan2
- BEND2 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1238581335, COSV101191809; called by muse, mutect2, varscan2
- BEND3 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs782329696, COSV64680382; called by muse, mutect2, varscan2
- BEND5 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1415597483, COSV65718585; called by muse, mutect2, varscan2
- BEND5 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs1180213008, COSV65718601; called by muse, mutect2, varscan2
- BHLHE40 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV56575152; called by muse, mutect2, varscan2
- BICD1 | c.1684C>T p.R562* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as rs200597704; called by muse, mutect2
- BICD2 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as rs150861652, CM141042; called by muse, mutect2, varscan2
- BICD2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776953074, COSV63548161, COSV63550827; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BICRA | c.2935dup p.A979Gfs*86 | Frame Shift Ins (INS) | VAF 34/52 reads (65%) | catalogued as rs756990560; called by mutect2, varscan2
- BID | c.505C>T p.R169W (on ENST00000317361 / NM_197966.2; = p.R123W on NM_001196.4) | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs749451392, COSV58006644; called by muse, mutect2, varscan2
- BIN2 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs1280868924, COSV57207035; called by muse, mutect2, varscan2
- BIRC6 | c.14395C>T p.R4799C | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs759980874, COSV101429007; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs749399763; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1400329743, COSV63244190, COSV63244592; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4790C>T p.A1597V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs376411022, COSV63244831; ClinVar: conflicting interpretations of pathogenicity; called by muse, varscan2
- BLMH | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480557860, COSV55585417; called by muse, mutect2, varscan2
- BMERB1 | c.317C>A p.T106N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs757365966, COSV55509794; called by muse, mutect2, varscan2
- BMP1 | c.1939G>A p.D647N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257093673, COSV60484635; called by muse, mutect2, varscan2
- BMP15 | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as rs782589890; called by muse, mutect2, varscan2
- BMP3 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779660778, COSV51082365; called by muse, mutect2, varscan2
- BMP8B | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62928460, COSV62928745; called by muse, mutect2, varscan2
- BMS1 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.294); catalogued as rs1260684348, COSV65734717; called by muse, mutect2, varscan2
- BNC2 | c.1759A>G p.T587A | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs141541187; called by muse, varscan2
- BOD1L1 | c.3371C>A p.S1124Y | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.176); catalogued as COSV99240348; called by muse, mutect2, varscan2
- BOD1L1 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs745506657; called by muse, mutect2, varscan2
- BOD1L1 | c.2534C>T p.S845L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as rs1402621092; called by muse, mutect2, varscan2
- BOD1L1 | c.301A>G p.T101A | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs1220779862; called by muse, mutect2, varscan2
- BOP1 | c.2218G>A p.G740R | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1020723782; called by muse, mutect2, varscan2
- BOP1 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1261173428; called by muse, mutect2, varscan2
- BPGM | c.413A>G p.N138S | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1440262590; called by muse, mutect2, varscan2
- BPIFA3 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs138661121; called by muse, mutect2, varscan2
- BPIFB2 | c.309C>T p.R103= | Splice Region (SNP) | VAF 17/56 reads (30%) | catalogued as rs750973615; called by muse, mutect2, varscan2
- BPIFB4 | c.1340G>A p.G447D | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); catalogued as rs962646701; called by muse, mutect2, varscan2
- BPNT2 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148507660, COSV52907029; called by muse, mutect2, varscan2
- BPTF | c.4556G>A p.R1519Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs954187761; called by muse, mutect2, varscan2
- BRCA1 | c.3944C>T p.P1315L | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV58785573; called by muse, mutect2, varscan2
- BRCA2 | c.3900G>T p.M1300I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.053); catalogued as CD128981; called by muse, varscan2
16,231 further variants in this file (11,429 protein-altering or splice-affecting, 4,396 silent, 406 other) are not listed here.
